Surgical pathology report (de-identified scan), TCGA case TCGA-AO-A128, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site MSKCC, specimen TCGA-AO-A128-01A (Primary Tumor).

[page 1 of 5]
.....

Clinical Diagnosis & History:

Patient with right breast mass, suspicious BMG, FNA positive adenocarcinoma.

Specimens Submitted:

- 1: SP: Sentinel node #1, level 1, right axilla
- 2: SP: Sentinel node #2, level 2, right axilla
- 3: SP: Sentinel node #3, level 2, right axilla
- 4: SP: Right breast cancer
- 5: SP: Posterior margin, right breast
- 6: SP: Anterior medial margin, right breast
- 7: SP: Non-sentinel tissue, right axilla

DIAGNOSIS:

- 1) SENTINEL LYMPH NODE #1, LEVEL I, RIGHT AXILLA; BIOPSY:
- THREE BENIGN LYMPH NODES (0/3).
- DEEPER LEVEL RECUTS AND SPECIAL STAINS (AE1:AE3 AND CAM 5.2) ARE ALSO NEGATIVE FOR METASTASIS.
- 2) SENTINEL LYMPH NODE #2, LEVEL II, RIGHT AXILLA; BIOPSY:
- TWO BENIGN LYMPH NODES (0/2).
- DEEPER LEVEL RECUTS AND SPECIAL STAINS (AE1:AE3 AND CAM 5.2) ARE ALSO NEGATIVE FOR METASTASIS.
- 3) SENTINEL LYMPH NODE #3, LEVEL II, RIGHT AXILLA; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- DEEPER LEVEL RECUTS AND SPECIAL STAINS (AE1:AE3 AND CAM 5.2) ARE ALSO NEGATIVE FOR METASTASIS.
- 4) BREAST, RIGHT; EXCISION:
- INVASIVE DUCTAL CARCINOMA, NOS TYPE, HISTOLOGIC GRADE III/III (SLIGHT OR NO TUBULE FORMATION), NUCLEAR GRADE III/III (MARKED VARIATION IN SIZE AND SHAPE), MEASURING 4.0 CM IN LARGEST DIMENSION GROSSLY.
- NO DUCTAL CARCINOMA IN SITU (DCIS) IS IDENTIFIED.
- NO CALCIFICATIONS ARE IDENTIFIED IN THE INVASIVE CARCINOMA.
- NO VASCULAR INVASION IS NOTED.
- NO INVOLVEMENT OF THE SURGICAL MARGINS BY INVASIVE CARCINOMA IS IDENTIFIED.
- THE NON-NEOPLASTIC BREAST TISSUE IS UNREMARKABLE.
- THE TUMOR IS NEGATIVE FOR ER, PR, AND HER2-NEU (STAINING INTENSITY OF 0).

PATH
REPORT

** Continued on next page **

1CD-0-3

carcinoma, infiltrating duct, NOS 8500/3
Site breast, NOS C50.9 lw 10/22/11

[page 2 of 5]
2

- 5) BREAST, RIGHT, POSTERIOR MARGIN; EXCISION:
- FIBROADIPOSE TISSUE.
- NO TUMOR SEEN.
- 6) BREAST, RIGHT, ANTERIOR MEDIAL MARGIN; EXCISION:
- FIBROCYSTIC CHANGES.
- SCLEROSING ADENOSIS.
- FLORID DUCTAL HYPERPLASIA.
- MICROCALCIFICATIONS IN BENIGN DUCTS.
- 7) NON-SENTINEL LYMPH NODE, RIGHT AXILLA; BIOPSY:
- NINE BENIGN LYMPH NODES (0/9).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	AE1:AE3	
	CAM 5.2	
	IMM RECUT	
	NEG CONT	
	AE1:AE3	
	CAM 5.2	
	IMM RECUT	
	NEG CONT	
	AE1:AE3	
	CAM 5.2	
	IMM RECUT	
	NEG CONT	
	ER-C	
	PR-C	
	HER2-C	
	AE1:AE3	
	CAM 5.2	
	S-100	
	HMB-45	
	A103	
	CD30 BERH2	
	CD45 (LCA)	
	ALK	
	Berep4	
	IMM RECUT	
	NEG CONT	
	NEG-HER2	
	P53	
	IMM RECUT	
	NEG CONT	

PATH
REPORT

** Continued on next page **

[page 3 of 5]
Gross Description:

1) The specimen is received fresh for frozen section diagnosis, labeled, "Sentinel node #1, level 1, right axilla". It consists of one lymph node, measuring 2.0 x 0.4 x 0.2 cm. It was bisected and entirely submitted.

Summary of Sections:

FSC frozen section control

2) The specimen is received fresh for frozen section diagnosis, labeled, "Sentinel node #2, level 2, right axilla". It consists of one lymph node, measuring 1.0 x 0.3 x 0.2 cm. The lymph node is bisected and entirely submitted for frozen evaluation.

Summary of Sections:

FSC frozen section control

3) The specimen is received fresh for frozen section diagnosis, labeled, "Sentinel node #3, level 2, right axilla". It consists of one lymph node, measuring 0.8 x 0.2 x 0.2 cm. The lymph node is bisected and entirely submitted for frozen evaluation.

Summary of Sections:

FSC frozen section control

4) The specimen is received fresh for frozen section diagnosis, labeled, "Right breast cancer, (long stitch lateral and short superior)". It consists of a segment of soft yellow fatty tissue, measuring 12.0 x 12.5 x 4.5 cm. A long and short stitch are identified designating the superior and lateral margins. The specimen is inked as follows: posterior-black, anterior-yellow, superior-blue, and inferior-red. The specimen is serially sectioned and a cut-surface revealed a well-circumscribed soft tan to yellow tumor mass, measuring 4.0 x 2.5 x 2.5 cm. This is located 1.5 cm from the anterior margin and 1.0 cm from the posterior margin, 2.5 cm from the superior margin and 2.0 cm from the inferior margin, 6.0 cm from the medial margin and 2.0 cm from the lateral margin. The remaining breast is soft yellow fatty tissue with irregular fibrosis. No other separate lesion is identified. Representative tissue is submitted for frozen evaluation and representative sections are submitted.

Summary of Sections:

FSC frozen section control

LM lateral margin

MM medial margin

AM anterior margin

PM posterior margin

SM superior margin

IM inferior margin

PATH
REPORT

** Continued on next page **

[page 4 of 5]
4

T tumor mass with surrounding tissue
R representative sections of the breast

----- Page 4 of 5

5) The specimen is received fresh, labeled, "Posterior margin, right breast, (stitch marks new margin to ink)". It consists of one segment of soft yellow fatty tissue, measuring 10.0 x 2.2 x 0.8 cm. A black suture is noted on one side of the specimen, which is inked black. The specimen is serially sectioned and cut-surfaces revealed a soft yellow to tan tissue. No tumor is identified. The entire specimen is submitted.

Summary of Sections:
U - undesignated

6) The specimen is received fresh, labeled, "Anterior medial margin, right breast, (stitch marks new margin to ink)". It consists of one segment of soft yellow to tan tissue, measuring 3.0 x 3.0 x 2.0 cm. Multiple cysts containing dark-colored fluid is identified. The suture site of the specimen is inked black. The specimen is serially sectioned. A cut-surface revealed a soft tan to yellow tissue with multiple cysts. No firm mass is identified. The entire specimen is submitted.

Summary of Sections:
U - undesignated

7) The specimen is received in formalin, labeled, "Non-sentinel tissue, right axilla". It consists of multiple pieces of irregular tan to yellow fatty tissue. The aggregate measured 4.5 x 3.0 x 0.8 cm. Dissection revealed multiple soft tan lymph node with a sizes ranging from 0.3 to 0.9 cm. The entire lymphoid tissue is submitted.

Summary of Sections:
U undesignated

Summary of Sections:

Part 1: SP: Sentinel node #1, level 1, right axilla

Block	Sect.	Site	PCs
1		FSC	2

Part 2: SP: Sentinel node #2, level 2, right axilla

Block	Sect.	Site	PCs
1		FSC	2

PATH
REPORT

** Continued on next page **

[page 5 of 5]
Part 3: SP: Sentinel node #3, level 2, right axilla ----- Page 5 of 5

Block	Sect.	Site	PCs
1	FSC		2

Part 4: SP: Right breast cancer

Block	Sect.	Site	PCs
1		AM	1
1		FSC	1
1		IM	1
1		LM	1
1		MM	1
1		PM	1
7		R	7
1		SM	1
6		T	6

Part 5: SP: Posterior margin, right breast

Block	Sect.	Site	PCs
6	U		10

Part 6: SP: Anterior medial margin, right breast

Block	Sect.	Site	PCs
7	U		8

Part 7: SP: Non-sentinel tissue, right axilla

Block	Sect.	Site	PCs
4	U		10

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: BENIGN.
PERMANENT DIAGNOSIS: SAME.
- 2) FROZEN SECTION DIAGNOSIS: BENIGN.
PERMANENT DIAGNOSIS: SAME.
- 3) FROZEN SECTION DIAGNOSIS: BENIGN.
PERMANENT DIAGNOSIS: SAME.
- 4) FROZEN SECTION DIAGNOSIS: INVASIVE CARCINOMA.
PERMANENT DIAGNOSIS: SAME.

PATH
REPORT

** End of Report **

Source: NCI Genomic Data Commons file 1f7c3b39-83dc-482c-972d-d30c7790f9b1 (TCGA-AO-A128.03526CFD-0C3E-4ACB-AB26-3E0B0ED0ADA2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).